Somatic mutation profile of tumor specimen MP2PRT-PAVIPS-TBP1-A (aliquot MP2PRT-PAVIPS-TBP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVIPS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,269 days).
Specimen MP2PRT-PAVIPS-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 502372da-e077-4b47-bbb6-6737e609e411.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVIPS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVIPS-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8767f92d-d55a-4bf4-8ed3-3c1d9c259e34

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.6344T>C p.M2115T (on ENST00000297405 / NM_001363185.1; = p.M2011T on NM_052900.3) | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs1323595899; called by muse, mutect2, varscan2
- FOXA3 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867043290; called by muse, mutect2, varscan2
- KLHL29 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 95/752 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs561931922, COSV72086022; called by muse, mutect2, varscan2
- RBBP8NL | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1031847083; called by muse, mutect2
- RHBDF1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs542292412; called by muse, mutect2
- KLHL38 | c.623T>A p.L208H | Missense Mutation (SNP) | VAF 49/470 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PDHA2 | c.1013C>A p.A338D | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.493); called by muse, mutect2
- MSI1 | c.408C>T p.D136= | Silent (SNP) | VAF 57/414 reads (14%) | catalogued as rs755538859, COSV57456470; called by muse, mutect2, varscan2
